Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27T, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27T-01A (Primary Tumor).

[page 1 of 2]
ICB-0-3

Carcinoma, infiltrating lobular, NOS 8520/3

Site: breast, NOS C50.9 for 5/19/11

page 1 / 2

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **Multiple organ resection – right breast**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis:

Diagnostic Discrepancy		X

Examination performed on

Macroscopic description:

Right breast sized 21.5 x 14 x 4 cm removed without axillary tissues and with a skin flap of 15 x 7 cm. Tumour sized 3.0 x 1.4 x 1.8 cm on the boundary of outer quadrants, located 3 cm from the lower boundary, 3 cm from the base and 1 cm from the skin.

Microscopic description:

Carcinoma mammae invasivum- NHG2 (3+2+1:5 mitoses/10 HPF - visual area: 0.55mm).

Lesions of the type mastopathia fibrosa et cystica.

Metastases carcinomatosae in lymphonodis.

Infiltratio capsulae lymphonodi et telae perinodalis.

Histopathological diagnosis:

Invasive lobular carcinoma of the right breast

Compliance validated by:

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.

Negative reaction in invasive cancerous cells (Score=1+).

Compliance validated by

Examination performed on:

[page 2 of 2]
Examination: Histopathological examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on:

Examination result:

Carcinoma lobulare invasivum mammae dextrae.

Metastases carcinomatosae in lymphonodis axillae (No II/II) (NHG2, pT2, pN1a).

Following immunohistopathological tests were made:: E - cadheryna "-".

Compliance validated by

Source: NCI Genomic Data Commons file b113904a-5049-4c6a-a48e-f8cb14e0cf58 (TCGA-D8-A27T.15237FF6-A56E-4E05-B81D-B87E91B59917.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).